Gene-level copy-number profile of tumor specimen REBC-ACCD-TTP1-A from REBC case REBC-ACCD, project REBC-THYR (Comprehensive genomic characterization of radiation-related papillary thyroid cancer in the Ukraine). Sex at birth: male; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland.
Specimen REBC-ACCD-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b5e22bed-344b-4383-8e12-21be3e5a9666.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator REBC-ACCD-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,722 have no estimate.
https://portal.gdc.cancer.gov/files/184166a5-c460-46c1-a079-6fc7a49e7102

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 45; copy number 1: 3,497; copy number 2: 55,341; copy number 3: 12; copy number 4: 6.

Homozygous deletions (total copy number 0; autosomes only): 45 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:105,785,505–105,845,678, 2 genes (within-gene range 0–1): ATP6V1G1P1, IGHD.
- chr14:105,857,513–105,857,572, 1 gene (within-gene range 0–1): MIR4539.
- chr14:105,858,165–105,945,389, 42 genes (within-gene range 0–1): MIR4538, MIR4537, IGHJ6, IGHJ3P, IGHJ5, IGHJ4, IGHJ3, IGHJ2P, IGHJ2, IGHJ1, IGHD7-27, IGHJ1P, IGHD1-26, IGHD6-25, IGHD5-24, IGHD4-23, IGHD3-22, IGHD2-21, AC246787.2, IGHD1-20, IGHD6-19, IGHD5-18, IGHD4-17, IGHD3-16, IGHD2-15, IGHD1-14, IGHD6-13, IGHD5-12, IGHD4-11, IGHD3-10, IGHD3-9, IGHD2-8, IGHD1-7, IGHD6-6, IGHD5-5, IGHD4-4, IGHD3-3, IGHD2-2, FAM30A, IGHD1-1, IGHV6-1, IGHVII-1-1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 641. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
